Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABSE, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABSE-TTM1-A (Metastatic).

[page 1 of 24]
SURGICAL PATHOLOGY REPORT

NAME: [REDACTED]
Location: [REDACTED]
Medical Record #: [REDACTED]
Account #: [REDACTED]
Physician: [REDACTED]
Copy To: [REDACTED]

SURGICAL #: [REDACTED]
Date of Birth: [REDACTED]
Age/Sex: 59 F
Date Collected: [REDACTED] +0
Date Received: [REDACTED] +0

TISSUES: A. Submitted as: - SIGMOID COLON
B. Submitted as: - DISTAL SIGMOID RING
C. Submitted as: - PROXIMAL SIGMOID RING

PRE-OPERATIVE DIAGNOSIS:

SIGMOID POLYP; SIGMOID MASS

GROSS DESCRIPTION:

Container "A" submitted as a portion of sigmoid colon. Consists of a segment of colon measuring 14.0 cms. in length and 5.0 cms. in maximum transverse diameters. Approximately 1.5 cms. from the closest margin of resection, the colonic mucosa shows an elevated and focal ulcerated lesion which is coin shaped, slight elevated and contoured which measures 1.7 cms. in largest dimension. The proximal as well as the distal margins of resection of all areas of the colonic wall are unremarkable. No enlarged mesenteric lymphoid nodes are seen. Sections are embedded.

Container "B" submitted as distal sigmoid ring. Consists of a portion of bowel wall with some metallic sutures and measuring 1.0 x 0.8 x 0.2 cms. Sections are embedded.

Container "C" submitted as a proximal sigmoid ring. Consists of a circular shaped portion of bowel wall which measures 2.5 cms., transversely and 0.5 cms. in with width. Few metallic sutures are noted. Sections are embedded.

MICROSCOPIC DESCRIPTION:

A total of seven slides labeled "A" are examined. The sections from the grossly noted flat polypoid and coin shaped lesion of the sigmoid colon shows at this particular site the mucosa of the colon with numerous neoplastic glands invading the underlying submucosa and reaching the whole thickness of the muscularis propria. The tumor elicits a mild-to-moderate lymphocytic response. All the margins of resection are unremarkable. Two small mesenteric lymph nodes are free of malignancy.

The slide labeled "B" and "C" shows two portions of colon representing margins of resection which are unremarkable.

[page 2 of 24]
NAME:

FINAL DIAGNOSIS:

A1. SEGMENT OF SIGMOID COLON, AREA OF INVASIVE MODERATELY DIFFERENTIATED CARCINOMA, REACHING THE MUSCULARIS PROPRIA OF THE BOWEL WALL, MEASURING 1.7 CMS IN MAXIMUM TRANSVERSE DIAMETER.

2. MESENTERIC LYMPH NODES, NEGATIVE FOR MALIGNANCY. (0/2).

B&C. DISTAL AND PROXIMAL SURGICAL MARGINS OF RESECTION, UNREMARKABLE.

de +7
dt +7

SUMMARY FINDINGS:

MACROSCOPIC

Specimen Type: Sigmoid colectomy

Tumor Site: Sigmoid colon

Tumor Configuration: Ulcerative, coin shaped

Tumor Size: 1.7 cms

Mesorectum: Unremarkable

MICROSCOPIC

Histologic Type: Adenocarcinoma

Histologic Grade: Moderately differentiated, Grade 2

Pathologic Staging (pTNM): pT2, pN0, pMX

Lymph nodes: 0/2

Margins:

Proximal Margin: Uninvolved

Distal Margin: Uninvolved

Circumferential (Radial) Margin: Uninvolved

Mesenteric Margin: Unremarkable

Distance of invasive carcinoma from closest margin: 2.0 cms

Lymphatic Invasion (L): No

Venous Invasion (V): No

Perineural Invasion: No

Tumor Border Configuration: Infiltrative

Intratumoral/Peritumoral Lymphocytic Response: Mild to moderate

Signed By:

+7

[page 3 of 24]
Documents Review Report

MRN: [REDACTED]	DOB: [REDACTED]	Age: 65y	F
Admit Date: [REDACTED]	+1472	Provider: [REDACTED]	
Surgical Pathology	Last Updated: [REDACTED]	[Entered: [REDACTED]]	
Authorized By: [REDACTED]	Final, Revised, Signed in Full, General	+1498	

Ordering Physician: [REDACTED]

Patient Name: [REDACTED]

MR#: [REDACTED]

Specimen [REDACTED]

Taken: [REDACTED] +1472

Received: [REDACTED] +1472

Reported: [REDACTED] +1475

Specimen(s) Received

Left retroperitoneal mass

Addendum

Addendum

DIAGNOSIS: METASTATIC ADENOCARCINOMA CONSISTENT WITH COLON PRIMARY ORIGIN.

Source of Tissue: Left Retroperitoneal Mass

Case: [REDACTED]

Summary

Clinical History: The patient is a 63 year old female with a history of metastatic colon adenocarcinoma.

Mutational Analysis

KRAS: NEGATIVE

result Wild-type genotype
analysis Wild type at codons 12, 13 and 61; therefore this
sample is negative for a KRAS mutation.

BRAF: NEGATIVE

result Wild-type genotype
analysis Wild type at codons 464-469 and 600; therefore, this
sample is negative for BRAF mutation.

Agents associated WITH CLINICAL BENEFIT
ON NCCN COMPENDIUM:

Fluorouracil
Irinotecan
Cetuximab, panitumumab
Oxaliplatin

OFF NCCN COMPENDIUM:

Requested By: [REDACTED]

Printed From: [REDACTED]

[page 4 of 24]
Documents Review Report

MRN: [REDACTED]	DOB: [REDACTED]	Age: 65y	F
Admit Date: [REDACTED]	Provider: [REDACTED]		
Surgical Pathology	Last Updated: [REDACTED]	Entered: [REDACTED]	
Authored By: [REDACTED]	Final, Revised, Signed In Full, General		+1472

Nab-paclitaxel
Doxorubicin, liposomal-doxorubicin, epirubicin
Cisplatin, carboplatin
Gemcitabine
Pemetrexed
Sunitinib, sorafenib

Agents associated with LACK OF CLINICAL BENEFITS:

Lapatinib
Temozolomide
Trastuzumab

Addendum Comment

Testing performed and reported at [REDACTED]

Please see entire report from [REDACTED]

Final Diagnosis

Left retroperitoneal mass:

- Metastatic adenocarcinoma consistent with colon primary origin.

Note

Immunohistochemical stain for CK20 and CDX2 is strongly positive. CK7 is focally positive. The history of colonic adenocarcinoma is noted. The clinical history, the tumor morphology and the immunohistochemical stain profile are consistent with metastatic colonic adenocarcinoma.

The immunostains were developed and performance characteristics determined by [REDACTED]

They have not been cleared or approved by the U.S. Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. [REDACTED] is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Requested By: [REDACTED]

Printed From [REDACTED]

[page 5 of 24]
38/72

PAGE 1 of 12

Patient Information

Case Number:
Date Of Birth:
Sex: Female
SSN: N/A

Specimen Information

Primary Tumor Site: Colon (Large Intestine), NOS
Specimen Site: Retroperitoneum & Peritoneum
Specimen Collected: +1472
Specimen Received: +1478
Date Reported: +1490

Ordered By

Final Report

Clinical History

Per the submitted surgical pathology report, the patient is a 63 year-old female with a history of metastatic colon adenocarcinoma.

Pathologic Diagnosis

Left retroperitoneal mass: Metastatic adenocarcinoma consistent with colon primary origin.

Agents Associated
WITH CLINICAL BENEFIT

ON NCCN COMPENDIUM**

fluorouracil
irinotecan
cetuximab , panitumumab
oxaliplatin

OFF NCCN COMPENDIUM**

nab-paclitaxel
doxorubicin , liposomal-doxorubicin ,
epirubicin
cisplatin , carboplatin
gemcitabine
pemetrexed
sunitinib , sorafenib

Agents Associated With
LACK OF CLINICAL BENEFIT

lapatinib
temozolomide
trastuzumab

** FINAL REPORT **

An expert oncology consultation can be arranged if a request is made through our Client Services Department at

Patient:

Physician:

PATHOLOGY REPORT - Page 1 of 13

Patient:

DOB:

Discharged:

Service Dates:

REQ:

+1472-+1479

[page 6 of 24]
39/72

Specimens Received

The specimens consist of:

+1472

1 (A) Tissue Biopsy Formalin Vial -

and Retroperitoneal"

1 (B) Tissue Biopsy RNAlater -

Received is a single formalin filled specimen container labeled with the patient's name, medical record number and "retroperitoneal". It contains two portions of pale-tan-yellow brown soft tissue measuring 1.4 x 0.8 x 0.5 cm and 1.1 x 0.8 x 0.7 cm. The specimen is entirely submitted in cassette A.

Interpretation

H&E prepared from the tissue submitted in formalin for Target Now testing shows fibroadipose tissue with a moderately differentiated adenocarcinoma which is concordant with the patient submitted pathology diagnosis per surgical pathology report.

**** FINAL REPORT ****

Physician:

PATHOLOGY REPORT - Page 2 of 13

Patient:

MRN:

Discharged:

Printed:

Service Dates:

Copy for:

REQ:

+1472-+1479

[page 7 of 24]
TARGET NOW¹ SUMMARY - AGENTS ASSOCIATED WITH CLINICAL BENEFIT

Agents Associated With CLINICAL BENEFIT	Biomarker	Result	Method	Summary Statement
fluorouracil	TYMS	Under Expressed	Microarray-Illumina	Low expression of TS has been associated with benefit from fluoropyrimidines.
	TS	Negative	IHC	
irinotecan	TOPO1	Above Threshold	IHC	High expression of TOPO1 has been associated with benefit from irinotecan.
cetuximab, panitumumab	KRAS	Wild type genotype	Molecular	Wild-type BRAF and KRAS are associated with benefit from EGFR-targeted antibodies.
	BRAF	Wild type genotype	Molecular	
	PTEN	Below Threshold	IHC	
nab-paclitaxel	SPARC Polyclonal	Above Threshold	IHC	High expression of SPARC has been associated with benefit from nab-Paclitaxel.
	SPARC	Over Expressed	Microarray-Illumina	
doxorubicin, liposomal-doxorubicin, epirubicin	TOP2A	Above Threshold	IHC	High expression of TOPO2A and TOPO2B have been associated with benefit from anthracycline-based therapy.
	TOP2B	Over Expressed	Microarray-Illumina	
cisplatin, carboplatin, oxaliplatin	ERCC1	Negative	IHC	Low expression of ERCC1 has been associated with benefit from platinum analogs.
gemcitabine	DCK	Over Expressed	Microarray-Illumina	Low expression of RRM1 and RRM2, and high expression of DCK, have been associated with benefit from gemcitabine.
	RRM2	Under Expressed	Microarray-Illumina	
	RRM1	Under Expressed	Microarray-Illumina	
pemetrexed	TS	Negative	IHC	Low expression of GART and TS has been associated with benefit from pemetrexed.
	GART	Under Expressed	Microarray-Illumina	
	TYMS	Under Expressed	Microarray-Illumina	
sunitinib, sorafenib	PDGFRB	Over Expressed	Microarray-Illumina	Over expression of PDGFRA and PDGFRB, and under expression of VHL have been associated with benefit from multi-targeted kinase inhibitors.
	VHL	Under Expressed	Microarray-Illumina	
	PDGFRA	Over Expressed	Microarray-Illumina	

**** FINAL REPORT ****

Patient: [REDACTED]

PATHOLOGY REPORT - Page 3 of 13

Patient: [REDACTED]

HRF: [REDACTED]

Discharged: [REDACTED]

Printed: [REDACTED]

Copy for: [REDACTED]

REQ: [REDACTED]

Service Dates: [REDACTED]

+1472-+1479

[page 8 of 24]
41/72

TARGET NOW[®] SUMMARY - Agents Associated with LACK OF CLINICAL BENEFIT

Agents Associated With LACK OF CLINICAL BENEFIT	Biomarker	Result	Method	Summary Statement
lapatinib	Her2/Neu	Negative	IHC	Low expression of HER2 has been associated with lack of benefit from HER2 targeted protein kinase inhibitor.
temozolomide	MGMT	Above Threshold	IHC	High expression of MGMT has been associated with lack of benefit from temozolomide.
trastuzumab	Her2/Neu	Negative	IHC	Low expression of HER2 has been associated with lack of benefit from HER2 targeted antibody.
	PTEN	Below Threshold	IHC	

**** FINAL REPORT ****

Patient: [REDACTED]

PATHOLOGY REPORT - Page 4 of 13

Patient: [REDACTED]

MR#: [REDACTED]

Discharged: [REDACTED]

Printed: [REDACTED]

Copy For: [REDACTED]

REQ: [REDACTED]

Service Dates: [REDACTED]

+1472-+1479

[page 9 of 24]
42/172

IHC Biomarker Detail

Biomarker	Agent Association	Patient Tumor		Threshold Biomarker Intensity/Percentage
		Staining Intensity	Percent Staining	
TOP01	✓	2	80	=0+ or <30% or <2+ or ≥2+ and ≥30%
SPARC Polyclonal	✓	2	30	=0+ or <2+ and <30% or ≥2+ and ≥30%
ERCC1	✓	2	20	<2+ or =2+ and <50% or ≥3+ and <10% or ≥2+ and ≥50% or ≥3+ and ≥10%
RRM1		2	15	=0+ or ≥2+ and ≥50%
TOP2A	✓	2	10	=0+ or <10% or ≥1+ and ≥10%
COX-2		2	2	=0+ or <2+ and <10% or ≥2+ and ≥10%
c-kit		2	1	=0+ and =100% or ≥2+ and ≥30%
MRP1		1	70	=0+ or =1+ and <10% or ≥1+ and ≥10%
PTEN	✓	1	70	=0+ or =1+ and ≤10% or ≥2+ and ≥10%
SPARC Monoclonal		1	60	=0+ or <2+ and <30% or ≥2+ and ≥30%
MGMT	✓	1	50	=0+ or =1+ and <10% or ≥1+ and ≥10%
PGP		1	30	=0+ or =1+ and <10% or ≥1+ and ≥10%
Androgen Receptor		0	100	=0+ and =100% or ≥1+ and ≥10%
ER		0	100	=0+ and =100% or ≥1+ and ≥10%
Her2/Neu	✓	0	100	≤1+ or =2+ and <10% or ≥3+ and >30%
PR		0	100	=0+ or ≥1+ and ≥10%
TS	✓	0	100	=0+ or =1+ and ≤25% or ≥2+ and ≥30%

* [REDACTED] has defined threshold levels of reactivity of IHC to establish cutoff points based on published evidence. Clones used: TOP01(1D6), SPARC Polyclonal(pyclonal), ERCC1(8F1), RRM1(pyclonal), TOP2A(3F6), c-kit(pyclonal), MRP1(33A6), PTEN(6H2.1), SPARC Monoclonal(12251), MGMT(MT23.3), PGP(C494), Androgen Receptor(AR27), ER(SP1), Her2/Neu(4B5), PR(1E2), TS(TS106).
** All Agent Associations are reflected in the Target Now Summary.

** FINAL REPORT **

Patient: [REDACTED]

[REDACTED]

PATHOLOGY REPORT - Page 5 of 13

Patient: [REDACTED]

MRN: [REDACTED]

Discharged: [REDACTED]

Printed: [REDACTED]

Copy for: [REDACTED]

REQ: [REDACTED]

Service Dates: [REDACTED]

+1472-+1479

[page 10 of 24]
Microarray Analysis of RNA Expression on RNAlater Tissue

Gene	Ratio	Expression*	Significant marker	Gene	Ratio	Expression*	Significant marker	Gene	Ratio	Expression*	Significant marker
CDA	0.06	Under Expressed		HCK	0.68	No Change		IGFBP4	1.40	No Change	
EPHA2	0.16	Under Expressed		ADA	0.68	No Change		SSTR5	1.47	No Change	
TK1	0.21	Under Expressed		ERCC1	0.71	No Change		BIRC5	1.47	No Change	
HIF1A	0.21	Under Expressed		CE92	0.76	No Change		SSTR4	1.62	No Change	
EGFR	0.26	Under Expressed		BRCA2	0.77	No Change		ESR1	1.65	No Change	
RRM2	0.28	Under Expressed	✓	TOP2A	0.80	No Change		RARA	1.72	Over Expressed	
ABCG2	0.32	Under Expressed		PTEN	0.81	No Change		PDGFRA	1.72	Over Expressed	✓
ABCC1	0.33	Under Expressed		DNMT3B	0.83	No Change		NFKB1	1.75	Over Expressed	
SRC	0.36	Under Expressed		NFKBIA	0.83	No Change		ERCC3	1.81	Over Expressed	
TYMS	0.37	Under Expressed	✓	RAF1	0.83	No Change		PDGFRB	1.81	Over Expressed	✓
ERBB2	0.39	Under Expressed		SIK2	0.84	No Change		HSP90AA1	1.85	Over Expressed	
DNMT3A	0.45	Under Expressed		LYN	0.85	No Change		BRCA1	1.87	Over Expressed	
GSTP1	0.45	Under Expressed		MGMT	0.85	No Change		LCK	1.89	Over Expressed	
GART	0.47	Under Expressed	✓	YES1	0.89	No Change		DNMT1	2.04	Over Expressed	
VHL	0.47	Under Expressed	✓	PGP	0.94	No Change		TOP2B	2.05	Over Expressed	✓
FOLR2	0.48	Under Expressed		TXNRD1	0.94	No Change		PDGFC	2.12	Over Expressed	
HDAC1	0.48	Under Expressed		MSH2	1.08	No Change		IGFBP5	2.14	Over Expressed	
OGFR	0.49	Under Expressed		CD33	1.10	No Change		PARP1	2.18	Over Expressed	
SSTR1	0.49	Under Expressed		FLT1	1.14	No Change		POLA1	2.60	Over Expressed	
TOP1	0.49	Under Expressed		MLH1	1.16	No Change		DCK	2.68	Over Expressed	✓
RRM1	0.52	Under Expressed	✓	FYN	1.18	No Change		ASNS	2.69	Over Expressed	
KIT	0.54	Under Expressed		SSTR3	1.20	No Change		SPARC	2.77	Over Expressed	✓
PTGS2	0.56	Under Expressed		IGFBP3	1.21	No Change		ECGF1	2.84	Over Expressed	
GNRH1	0.56	Under Expressed		IL2RA	1.33	No Change		RXRβ	3.14	Over Expressed	
VDR	0.64	Under Expressed		KDR	1.35	No Change		RRM2B	4.21	Over Expressed	
ZAP70	0.84	No Change		PGR	1.37	No Change		MET	5.80	Over Expressed	
AR	0.65	No Change		TNF	1.39	No Change		VEGFA	10.11	Over Expressed	

* "No Change" indicates that there is no difference in expression for this gene between the tumor and control tissues at a significance level of $p \leq 0.001$. A significance level of $p \leq 0.001$ has been chosen since genes passing this threshold can be validated as differentially expressed by alternative methods approximately 95% of the time.

** FINAL REPORT **

Patient: [REDACTED]

PATHOLOGY REPORT - Page 6 of 13

Patient: [REDACTED]

MRB: [REDACTED]

Discharged: [REDACTED]

Printed: [REDACTED]

Copy for: [REDACTED]

REQ: [REDACTED]

Service Dates [REDACTED]

[page 11 of 24]
44/72

Not Informative*

Genes						
BCL2	CD52	DHFR	MS4A1	NFKB2	RXRG	SSTR2

* "Not informative" indicates that the data obtained for either the patient sample or the control sample were not of sufficiently high quality to confidently evaluate the expression level of that particular RNA transcript

Methodology

Total RNA is extracted from tumor tissue and is converted to cDNA. This cDNA sample is then subjected to a whole genome (29K) microarray analysis using Illumina cDNA-mediated annealing, selection, extension and ligation (DASL) process. The expression of a subset of 88 genes are then compared to a tissue specific normal control and the relative expression ratios of these 88 target genes is determined as well as the statistical significance of the differential expression. The ability of this assay to detect expression changes is directly proportional to the amount of tumor nuclei present in the patient sample. Samples with 20% tumor nuclei are ~65% concordant when compared to samples with >95% tumor nuclei with an R-squared>0.99.

**** FINAL REPORT ****

Patient: [REDACTED]

PATHOLOGY REPORT - Page 7 of 13

Patient: [REDACTED]

HR#:

Discharged:

Service Dates:

Copy for:

REQ:

+1472-+1479

[page 12 of 24]
MUTATIONAL ANALYSIS

Gene	Analysis	Result	Agent Association
BRAF	Wild type at codons 464-469, and 600. Therefore, this sample is negative for a BRAF mutation.	Wild type genotype	✓
	Procedure: Direct sequence analysis was performed on genomic DNA isolated from a formalin-fixed paraffin-embedded tumor sample using custom primers designed to flank, amplify, and sequence codons 464-469 of exon 11 and codon 600 of exon 15 in the BRAF gene located at 7q34. This test has a sensitivity to detect as low as approximately 20% population of cells containing a BRAF mutation in a background of non-mutant normal (or wild type) cells.		
KRAS	Wild type at codons 12, 13, and 61. Therefore, this sample is negative for a KRAS mutation.	Wild type genotype	✓
	Procedure: Direct sequence analysis was performed on genomic DNA isolated from a formalin-fixed paraffin-embedded (FFPE) tumor sample provided using custom primers designed to flank, amplify, and sequence codons 12 and 13 in exon 2 and codon 61 in exon 3 of the KRAS gene. A total of 9 nucleotides in these 3 regions were evaluated for any nonsynonymous alterations that would result in an amino acid change in the protein. Mutations occurring outside of these regions will not be detected by this assay. The NCBI RefSeq human reference sequence NM_033360.2 was used for comparative analysis. The limit of mutation detection for dideoxy sequencing of DNA isolated from FFPE tissues is approximately 20% mutant DNA in a background of wild-type DNA.		

Comments on Molecular Profile Analysis

The findings are consistent with a wild type KRAS genotype (No evidence of KRAS mutation).
The findings are consistent with a wild type BRAF genotype (No evidence of BRAF mutation).

**** FINAL REPORT ****

Patient: [REDACTED]

PATHOLOGY REPORT - Page 8 of 13		Printed: [REDACTED]	
Patient: [REDACTED]	MR#: [REDACTED]	Discharged: [REDACTED]	Service Dates: [REDACTED]
Copy for: [REDACTED]	REQ: [REDACTED]		

[page 13 of 24]
Appendix

BIOMARKER DESCRIPTION	
Target	Biomarker Description
BRAF	BRAF encodes a protein belonging to the raf/mil family of serine/threonine protein kinases. This protein plays a role in regulating the MAP kinase/ERK signaling pathway initiated by EGFR activation, which affects cell division, differentiation, and secretion. Mutations in this gene have been associated with various cancers, including non-Hodgkin lymphoma, colorectal cancer, malignant melanoma, thyroid carcinoma, non-small cell lung carcinoma, and adenocarcinoma of lung. Recent publications have also associated this mutation with a lack of response to cetuximab and panitumumab.
ERCC1	Nucleotide excision repair (NER) is a DNA repair mechanism necessary for the repair of DNA damage from a vast variety of sources including chemicals and ultraviolet (UV) light from the sun. NER is a particularly important mechanism by which cells prevent unwanted and potentially cancer-causing mutations. ERCC1 (excision repair cross-complementation group 1) is an important enzyme in the NER pathway. Some anticancer drugs kill cancer cells by causing DNA damage and hence need to overcome the effects of the DNA repair pathways to be effective. For example, platinum based drugs induce DNA cross-links that interfere with DNA replication and transcription. Tumors with low ERCC1 expression are more likely to benefit from platinum based DNA damaging agents while tumors that overexpress ERCC1 are more likely to be resistant to such drugs.
Her2/Neu	ErbB2/Her2 encodes a member of the epidermal growth factor (EGF) receptor family of receptor tyrosine kinases. Her2 has no ligand binding domain of its own and therefore cannot bind growth factors. It does however bind tightly to other ligand-bound EGF receptor family members, to form a heterodimer and enhances kinase-mediated activation of downstream signaling pathways leading to cell proliferation. Her2 is overexpressed in 15-30% of newly diagnosed breast cancers. Clinically, Her2 is a target for the monoclonal antibody Trastuzumab/Herceptin (which binds and blocks the receptor extracellularly) and the kinase inhibitor Lapatinib/Tykerb (which binds and blocks the receptor intracellularly).
KRAS	Proto-oncogene of the Kirsten rat sarcoma virus (KRAS); (rat sarcoma) is a signaling intermediate involved in many signaling cascades including the EGFR pathway. Oncogenic forms of KRAS due to mutations at activating hotspots cause the protein to be resistant to inactivation resulting in increased cellular proliferation and resistance to inactivation by EGFR inhibitors.
MGMT	O-6-methylguanine-DNA methyltransferase (MGMT) encodes a DNA repair enzyme. Loss of MGMT expression leads to compromised DNA repair in cells and may play a significant role in cancer formation. Low MGMT expression has been correlated with response to temozolomide.
PTEN	PTEN (phosphatase and tensin homolog) is a tumor suppressor gene that prevents cells from growing and dividing too rapidly and out of control. PTEN removes phosphate groups from a molecule called PIP3 to generate PIP2. This dephosphorylation helps to ensure the inhibition of the AKT cell survival pathway. PTEN protein is found in all types of cells and loss of PTEN function is one of the most common occurrences in multiple advanced human cancers. PTEN is an important mediator in signaling downstream of EGFR, which can be blocked by EGFR and Her2 targeted therapies. Loss of PTEN function is associated with a lack of response to these therapies.
SPARC Polyclonal	SPARC Polyclonal (secreted protein acidic and rich in cysteine) is a calcium-binding extracellular glycoprotein secreted by many types of cells. It has a normal role in wound repair, cell migration, and cell-matrix interactions. Its over-expression is thought to have a role in tumor invasion and angiogenesis. A few studies indicate that SPARC over-expression improves the response to the anti cancer drug, nab-paclitaxel. The improved response is thought to be related to SPARC's role in accumulating albumin and albumin targeted agents within tumor tissue.
TOP2A	TOP2A is an enzyme that alters the super coiling of double stranded DNA and allows chromosomal segregation into daughter cells. Due to its essential role in DNA synthesis and repair, and frequent over expression in tumors, TOP2A is an ideal target for antineoplastic agents. High expression and/or co-amplification of TOP2A and HER2 have been associated with benefit from anthracycline based therapy.
TOP2B1	Topoisomerase I is an enzyme that alters the supercoiling of double-stranded DNA. TopoI acts by transiently cutting one strand of the DNA to relax the coil and extend the DNA molecule. The regulation of DNA supercoiling is essential to DNA transcription and replication, when the DNA helix must unwind to permit the proper function of the enzymatic machinery involved in these processes. Higher expression of TopoI has been associated with response to first line chemotherapy containing Irinotecan, a TopoI inhibitor.
TS	Thymidylate synthase (TS) is an enzyme that generates thymidine monophosphate (dTMP), which get phosphorylated to thymidine triphosphate (dTTP) for use in DNA synthesis and repair. The reactions catalyzed by TS also yield dihydrofolate as a secondary product. As an anti-cancer chemotherapy target, thymidylate synthase can be inhibited by fluoropyrimidine or certain folate analogues. High TS has been associated with lack of response to fluoropyrimidine whereas low or no TS expression has been associated with improved clinical response to fluoropyrimidine.

** FINAL REPORT **

Patient: [REDACTED]

PATHOLOGY REPORT - Page 9 of 13

Printed: [REDACTED]

Patient: [REDACTED]

MR#: [REDACTED]

Discharged: [REDACTED]

Service Dates: [REDACTED]

Copy for: [REDACTED]

REC: [REDACTED]

[page 14 of 24]
LITERATURE LEVEL of EVIDENCE

Agents Associated With CLINICAL BENEFIT	Reference	Level of Evidence
fluorouracil	Paradiso, A., G. Simone, et al. (2000). "Thymidylate synthase and p53 primary tumour expression as predictive factors for advanced colorectal cancer patients." Br J Cancer 82(3): 560-7.	II-3 / Good
fluorouracil	Popat, S., Z. Chen, et al. (2005). "A prospective, blinded analysis of thymidylate synthase and p53 expression as prognostic markers in the adjuvant treatment of colorectal cancer." Ann Oncol 17(12): 1810-7.	II-2 / Good
fluorouracil	Lenz, H. J., K. Heyashi, et al. (1996). "p53 point mutations and thymidylate synthase messenger RNA levels in disseminated colorectal cancer: an analysis of response and survival." Clin Cancer Res 4(5): 1243-50.	II-3 / Good
Irinotecan	Braun, M.S., M.T. Seymour, et al. (2008). "Predictive biomarkers of chemotherapy efficacy in colorectal cancer: results from the UK MRC FOCUS trial." J Clin Oncol 26(16): 2690-6.	II-1 / Good
cetuximab, panitumumab	Peters, M., J. Gansert, et al. (2010). "Randomized Phase III Study of Panitumumab With Fluorouracil, Leucovorin, and Irinotecan (FOLFIRI) Compared with FOLFIRI Alone as Second-Line Treatment in Patients with Metastatic Colorectal Cancer." J Clin Oncol 28: 4706-4713.	I / Good
cetuximab, panitumumab	Laurent-Puig, P., F. Pensult-Lorca, et al. (2009). "Analysis of PTEN, BRAF, and EGFR Status in Determining Benefit From Cetuximab Therapy in Wild-Type KRAS Metastatic Colon Cancer." J Clin Oncol 27(35): 5824-5830.	II-2 / Good
cetuximab, panitumumab	Douillard, J.-Y., J. Gansert, et al. (2010). "Randomized, Phase III Trial of Panitumumab with Infusional Fluorouracil, Leucovorin, and Oxaliplatin (FOLFOX4) Versus FOLFOX4 Alone as First-Line Treatment in Patients With Previously Untreated Metastatic Colorectal Cancer: The PRIME Study." J Clin Oncol 28: 4697-4705.	I / Good
cetuximab, panitumumab	Di Nicolantonio, F., et al. Wild-type BRAF is required for response to panitumumab or cetuximab in metastatic colorectal cancer. J Clin Oncol , 2008. 26(35): p. 5705-12.	II-3 / Good
nab-paclitaxel	Desai, N., Soon-Shiong, P., et al. (2009). "SPARC Expression Correlates with Tumor Response to Albumin-Bound Paclitaxel in Head and Neck Cancer Patients." Translational Oncology 2(2): 58-64.	II-3 / Good
nab-paclitaxel	Yardley, D.A., et al. Phase II study of neoadjuvant gemcitabine, epirubicin, and albumin-bound nab paclitaxel (GEA) in locally advanced breast cancer with SPARC tumor assessments. J Clin Oncol (May 20 suppl): abstr 603. 2008. 26.	III / Good
nab-paclitaxel	Razitsky, E., et al. Phase II study of neoadjuvant bevacizumab and trastuzumab administered with albumin-bound paclitaxel (nab-paclitaxel) and carboplatin in HER2+ locally advanced breast cancer. J Clin Oncol (May 20 suppl): abstr 527. 2008.	III / Good
doxorubicin, liposomal-doxorubicin, epirubicin	Dingemans, A.-M. C., G. Glasziou, et al. (1999). "Expression of DNA Topoisomerase II- α and Topoisomerase II- β Genes Predicts Survival and Response to Chemotherapy in Patients with Small Cell Lung Cancer." Clin Cancer Res (5): 2048-2056.	II-3 / Good
doxorubicin, liposomal-doxorubicin, epirubicin	Mukherjee, A., S. Chan, et al. (2010). "TOP2A protein expression predicts response to anthracycline combination neo-adjuvant chemotherapy in locally advanced primary breast cancer." Br J Cancer Advance online publication. 2 November 2010.	II-3 / Good
doxorubicin, liposomal-doxorubicin, epirubicin	Durbecq, V., M. Peetersmans, et al. (2004). "Topoisomerase-II alpha expression as a predictive marker in a population of advanced breast cancer patients randomly treated either with single-agent doxorubicin or single-agent docetaxel." Mol Cancer Ther 3(10): 1207-14.	II-2 / Good
cisplatin, carboplatin, oxaliplatin	Kim, Y.H., Ishii G, et al. (2009). "Expression of breast cancer resistance protein is associated with a poor clinical outcome in patients with small-cell lung cancer." Lung Cancer 65(1):105-11.	II-3 / Good
cisplatin, carboplatin, oxaliplatin	Yeh, K., G. Ishii, et al. (2004). "Breast cancer resistance protein impacts clinical outcome in platinum-based chemotherapy for advanced non-small cell lung cancer." Clin Cancer Res 10(5): 1691-7.	II-3 / Fair
cisplatin, carboplatin, oxaliplatin	Xwon, H.C., et al., Prognostic value of expression of ERCC1, thymidylate synthase, and glutathione S-transferase P1 for 5-fluorouracil/oxaliplatin chemotherapy in advanced gastric cancer. Ann Oncol , 2007. 18(3): p. 504-9	II-3 / Good

** FINAL REPORT **

Patient: [REDACTED]

PATHOLOGY REPORT - Page 10 of 13

Printed [REDACTED]

Patient: [REDACTED]

Discharged: [REDACTED]

Service Dates: [REDACTED]

Copy for: [REDACTED]

REQ: [REDACTED]

[page 15 of 24]
LITERATURE LEVEL of EVIDENCE

Agents Associated With LACK OF CLINICAL BENEFIT	Reference	Level of Evidence
lapatinib	Xia, W., I. Husain, et al. (2007). "Lapatinib on-tumor activity is not dependent upon phosphatase and tensin homologue deleted on chromosome 10 in ErbB2-overexpressing breast cancers." Cancer Res 67(3): 1170-5.	II-3 / Good
lapatinib	Press, M. F., R. S. Finn, et al. (2008). "HER-2 gene amplification, HER-2 and epidermal growth factor receptor mRNA and protein expression, and lapatinib efficacy in women with metastatic breast cancer." Clin Cancer Res 14(23): 7661-70.	II-1 / Good
temozolomide	Sonoda, Y., T. Tomihaga, et al. (2010). "O6-Methylguanine DNA methyltransferase determined by promoter hypermethylation and immunohistochemical expression is correlated with progression-free survival in patients with glioblastoma." Int J Clin Oncol 15: 352-358.	II-3 / Fair
temozolomide	Spiegel-Kraeucker, S., W. Berger, et al. (2010). "O6-Methylguanine DNA methyltransferase protein expression in tumor cells predicts outcome of temozolomide therapy in glioblastoma patients." Neuro-Oncology 12(1): 28-36.	II-3 / Good
temozolomide	Levin, N., I. Lavon, et al. (2006). "Progressive low-grade oligodendrogliomas: response to temozolomide and correlation between genetic profile and O6-methylguanine DNA methyltransferase protein expression." Cancer 106(6): 1759-65.	II-3 / Good
temozolomide	Felsberg, J., M.C.Sabel, et al. (2009). "Prognostic Significance of Molecular Markers and Extent of Resection in Primary Glioblastoma Patients." Clin Cancer Res 15(21): 6683-6693.	II-3 / Fair
temozolomide	Kovacs, K., B. W. Scheithauer, et al. (2008). "MGMT immunoreactivity predicts responsiveness of pituitary tumors to temozolomide therapy." Acta Neuropathol 115(2): 261-2.	III / Fair
trastuzumab	Seidman, A. D., M. N. Fomior, et al. (2001). "Weekly trastuzumab and paclitaxel therapy for metastatic breast cancer with analysis of efficacy by HER2 immunophenotype and gene amplification." J Clin Oncol 19(10): 2587-95, 2.	II-2 / Good
trastuzumab	Fujita, T., H. Doi, et al. (2006). "PTEN activity could be a predictive marker of trastuzumab efficacy in the treatment of ErbB2-overexpressing breast cancer." Br J Cancer 94(2): 247-52.	II-3 / Good
trastuzumab	Berns, K., H. M. Horlings, et al. (2007). "A functional genetic approach identifies the PI3K pathway as a major determinant of trastuzumab resistance in breast cancer." Cancer Cell 12(4): 395-402.	II-2 / Good
trastuzumab	Negata, Y., K. H. Lin, et al. (2004). "PTEN activation contributes to tumor inhibition by trastuzumab, and loss of PTEN predicts trastuzumab resistance in patients." Cancer Cell 6(2): 117-27.	II-3 / Good

** FINAL REPORT **

Patient: [REDACTED]

PATHOLOGY REPORT - Page 11 of 13

Printed: [REDACTED]

Patient: [REDACTED]

MR#: [REDACTED]

Discharged: [REDACTED]

Service Dates: [REDACTED]

Copy for: [REDACTED]

REQ: [REDACTED]

[page 16 of 24]
LITERATURE LEVEL OF EVIDENCE ASSESSMENT FRAMEWORK

Study Design		Study Validity	
Hierarchy of Design	Criteria	Grade	Criteria
I	Evidence obtained from at least one properly designed randomized controlled trial.	Good	The study is judged to be valid and relevant as regards results, statistical analysis, and conclusions and shows no significant flaws.
II-1	Evidence obtained from well-designed controlled trials without randomization.	Fair	The study is judged to be valid and relevant as regards results, statistical analysis, and conclusions, but contains at least one significant but not fatal flaw.
II-2	Evidence obtained from well-designed cohort or case-control analytic studies, preferably from more than one center or research group.	Poor	The study is judged to have a fatal flaw such that the conclusions are not valid for the purposes of this test.
II-3	Evidence obtained from multiple time series with or without the intervention. Dramatic results in uncontrolled trials might also be regarded as this type of evidence.		
III	Opinions of respected authorities, based on clinical experience, descriptive studies, or reports of expert committees.		

* Adapted from Harris, T., D. Atkins, et al. (2001). "Current Methods of the U.S. Preventive Services Task Force." *Am J Prev Med* 20(2S):9

** FINAL REPORT **

Patient: [REDACTED]

PATHOLOGY REPORT - Page 12 of 13

Patient: [REDACTED]

MR#: [REDACTED]

Discharged: [REDACTED]

Printed: [REDACTED]

Copy for: [REDACTED]

REQ: [REDACTED]

Service Dates: [REDACTED]

[page 17 of 24]
70/71

Patient Results

Age: 65 Female

Date of Birth:

CT Abd/Pelvis with contrast

1 or more Final Results
Received

+1464

Clinical Information: Colon cancer.

Technique: Helical CT of the abdomen without contrast followed by helical CT of the abdomen and pelvis with 100 mL of Visipaque 320 IV contrast. Triple phase protocol was performed through the upper abdomen with portal venous and delayed images through the pelvis. Oral bowel opacification was also used.

Comparison: Outside CT abdomen and pelvis on +1427 Outside CT abdomen pelvis on

+1339

+1427

Findings:

LUNG BASES: Clear.

LIVER: Negative for mass. Slight fatty infiltration.

BILIARY TREE: Unremarkable.

GALLBLADDER: Unremarkable.

ADRENALS: Unremarkable.

PANCREAS: Unremarkable.

SPLEEN: Unremarkable.

KIDNEYS: Functional, no masses.

GASTROINTESTINAL TRACT: Stable sigmoid anastomosis. There are tiny mesenteric nodes but no evidence of recurrent mass.

LYMPH NODES: The irregular mass medial to the left common iliac artery is 1.8 cm x 2.5 cm, image 5-64, essentially unchanged since +1339. Vague presacral fat density is also stable, image 5-73. A 5 mm presacral node, likely superior hemorrhoidal, on image 5-74 is decreased from 0.6 cm in

-1339

MESENTERY AND OMENTUM: Unremarkable.

ABDOMINAL AND PELVIC WALL: Unremarkable.

AORTA AND OTHER VESSELS: Atherosclerotic changes.

BONES: Degenerative changes.

OTHER: Bladder is negative. Status post hysterectomy.

IMPRESSION

1. Aside from mild fatty infiltration, the liver remains negative.
2. Stable left common iliac and distal periaortic mass. Hypermetabolism within it has been decreasing on outside PET CT scan. Possibilities include positive response to chemotherapy or resolving inflammatory lesion. The appearance and chronicity favor the former.
3. A small presacral node has decreased slightly.
4. Stable sigmoid anastomosis.

+1477

XA Guid PICC Line Placement

1 or more Final Results
Received

XA Guid PICC Line Placement

Final

[page 18 of 24]
69/71

Patient Results

Age: 65 Female

Date of Birth:

+144

CT Chest With Contrast

1 or more Final Results
Received

Indication: Colon cancer. Cough. +1339

Comparison: Abdomen/pelvis CT No previous chest CTs.

Technique: Helical CT imaging of the chest utilizing IV contrast.

Findings:

3 mm nodule, right middle lobe, image #30. 4 mm nodule, right middle lobe, image #34. 4 mm pleural based nodule, right lower lobe, image #30. No pulmonary consolidation, infiltrate, or pleural effusion.

No significant mediastinal or hilar lymphadenopathy. 9 mm short axis right axillary node. Atheromatous change, thoracic aorta, without aneurysm or dissection. No pericardial effusion. Hepatic steatosis. Stable mildly enlarged peripancreatic, celiac, gastrohepatic, and right paracaval lymph nodes. Largest measures 1.2 cm short axis. Visualized upper abdominal structures are otherwise unremarkable. Degenerative changes of the spine. No evidence of bony thorax metastases.

Impression:

1. Three small (4 mm or less) right-sided pulmonary nodules. Consider followup imaging to assess stability.
2. No pulmonary infiltrate, consolidation, or pleural effusion.
3. 9 mm short axis right axillary lymph node. No mediastinal or hilar lymphadenopathy.
4. Hepatic steatosis.
5. Stable mildly enlarged upper abdominal lymph nodes.

+1448

XR Consult Outside Study

1 or more Final Results
Received

XR Consult Outside Study

Final

Consult outside studies +1431 +1348

Outside PET/CT scan from [redacted] and [redacted] are not compatible with our software. Please refer to the outside report.

The CT scan of the abdomen and pelvis from the outside institution is from [redacted] +1339 More recent diagnostic CT scan is recommended if felt to be clinically indicated.

+1464

CT Abd/Pelvis with contrast

1 or more Final Results
Received

CT Abd/Pelvis with contrast

Final

[page 19 of 24]
P. 001

Patient Name: [REDACTED] **RADIOLOGY REPORT**
Unit No: [REDACTED] Exam Date: [REDACTED]

+1969

EXAM# [REDACTED] TYPE/EXAM
CT/CT ABD/PELVIS WITH CONTRAST

CT abdomen and pelvis with contrast

History: Colon cancer. Lupus. Low back pain.

Correlation: [REDACTED] +1802

Technique: Axial images following oral and intravenous contrast administration with postprocessed coronal reformats generated. 100 cc of Optiray 300 administered uneventfully. The chest is described under separate dictation as a dedicated study.

Abdomen: The liver and spleen are of normal size with no focal masses. Diffuse decreased density in the liver is compatible with fatty infiltration. The gallbladder is absent postsurgically. There is no biliary ductal dilatation. No adrenal lesion is seen. Pancreas is not remarkable. There are several porta hepatis and proximal peripancreatic nodes as before. The peripancreatic head node is 8 x 13 mm. There is a nonobstructing left mid pole renal calculus as before. There is evidence of a right renal cortical cyst in the lower pole as previously. Retroperitoneum shows atherosclerotic changes also affecting the renal arteries with no retroperitoneal collection. New interaortocaval adenopathy is appreciated with nodes of 7 x 9 mm and 10 x 18 mm present. Heavy atherosclerotic changes extend into the iliac vessels. The terminal ileal region is normal. There is no evidence of bowel obstruction.

Pelvis: There is no dependent fluid, mass or adenopathy. Postsurgical changes of the sigmoid colon are seen with no mass or constriction. Presacral space and pelvic sidewalls are not remarkable. Vaginal cuff region is not remarkable. Urinary bladder is normal. Inguinal region demonstrates femoral arterial calcification. There is minimal sigmoid mesenteric stranding present.

Bone windows screening demonstrates multifocal degenerative changes..

Impression:

1. New retroperitoneal (interaortocaval) adenopathy as well as stable

PAGE 1

(CONTINUED)

Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Age: 65 Sex: F
Acct No: [REDACTED] Loc: [REDACTED]
Exam Date: [REDACTED] Stat: [REDACTED]
Radiology No: [REDACTED] +1969

[page 20 of 24]
P. 002

Patient Name: [REDACTED] **RADIOLOGY REPORT**
Unit No: [REDACTED] Exam Date: [REDACTED]

+1969

TYPE/EXAM

CT/CT ABD/PELVIS WITH CONTRAST

<Continued>

pancreatic and portal region nodes. Consider PET evaluation to exclude recurrent metastatic disease.

2. No abnormality at the site of sigmoid resection or regional adenopathy though there is a small amount of nonspecific sigmoid mesenteric stranding.

PAGE 2

Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Age: 65 Sex: F
Acct No: [REDACTED] Loc: [REDACTED]
Exam Date: [REDACTED] Stat: [REDACTED]
Radiology No: [REDACTED]

+1969

[page 21 of 24]
Patient Name: [REDACTED]

Unit No: [REDACTED]

Exam Date: [REDACTED]

P. 003

EXAM#	TYPE/EXAM
[REDACTED]	CT/THORAX WITH CONTRAST
	CT/LOW OSMOLAR CONT. 300-399MG/

+1664

CT chest with contrast

Indication: History of lupus. Low back pain. History of chemotherapy for colon cancer [REDACTED] -1681-

Technique: Helical scans of the chest were performed during intravenous contrast injection. 100 cc Optiray 300 administered. Comparison is with [REDACTED] +1802

Findings: The lungs are well-inflated. There is no pulmonary mass or consolidation. The pulmonary vessels and bronchi exhibit normal caliber. There is a 3 mm nodule in the periphery of the right lower lobe which is unchanged. There is no lymph node enlargement in the mediastinum or pulmonary hila. Atherosclerotic plaque calcification is again seen in the coronary arteries and thoracic aorta. The chest wall soft tissues and ribs are unremarkable. Degenerative changes are seen at multiple levels throughout the thoracic spine. There is no lytic or sclerotic bone lesion. There is no axillary adenopathy.

Impression:

1. Stable 3 mm subpleural right lower lobe pulmonary nodule.
2. No new mediastinal mass or lymph node enlargement.

[REDACTED]

[REDACTED]

Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Age: 65 Sex: F
Acct No: [REDACTED] Loc: [REDACTED]
Exam Date: [REDACTED] Stat [REDACTED]
Radiology No: [REDACTED]

+1969

[page 22 of 24]
PATIENT NAME: [REDACTED]
BIRTH DATE: [REDACTED]
SEX: F
REQUESTING PHYS: [REDACTED]
ATTENDING PHYS: [REDACTED]
REASON: Colon cancer metastasized to multiple sites

MED REC NO: [REDACTED]
SERVICE DATE: [REDACTED] +2073
REPORT DATE: [REDACTED] +2073
ORDER FROM: [REDACTED]
ORDER: [REDACTED]
TRANSCRIBED: [REDACTED] +2073

Final

CT CHEST ABDOMEN PELVIS W IV CONTRAST

Study Result

RADIOLOGIST: [REDACTED]

EXAMINATION: CT SCAN OF THE CHEST, ABDOMEN AND PELVIS WITH CONTRAST, [REDACTED] +2073
[REDACTED] (DLP 3,369 mGy-cm).

CLINICAL DATA: Colon cancer which has metastasized to multiple sites.

Comparison is made to [REDACTED] +1348

The mediastinum is unremarkable without lymphadenopathy. Evaluation of the lungs demonstrates no infiltrates or nodules. The pleural spaces are clear.

There is mild fatty infiltration of the liver. There are no liver masses. Spleen, pancreas and kidneys are unremarkable. Evaluation of the bowel loops demonstrates no evidence for bowel obstruction or inflammation. The patient has had previous rectal resection.

The previously noted nodule adjacent to the left common iliac artery is no longer present. No new mass is seen. There is no lymphadenopathy.

IMPRESSION:

There are no masses or lymphadenopathy on today's scan. The previously noted nodule adjacent to the left common iliac artery is no longer present. There are no inflammatory changes or bowel obstruction.

Results

This study was interpreted by: [REDACTED]

This report has been reviewed and released by: [REDACTED]

[page 23 of 24]
PATIENT NAME: [REDACTED]
BIRTH DATE: [REDACTED]
SEX: F
REQUESTING PHYS: [REDACTED]
ATTENDING PHYS: [REDACTED]
REASON: Malignant neoplasm of colon, unspecified site

MED REC NO: [REDACTED]
SERVICE DATE: [REDACTED]
REPORT DATE: [REDACTED]
ORDER FROM: [REDACTED]
ORDER: [REDACTED]
TRANSCRIBED: [REDACTED]

+2782
+2782
+2782

Final

CT CHEST ABDOMEN PELVIS W IV CONTRAST

Study Result

RADIOLOGIST: [REDACTED]

CT CHEST, ABDOMEN AND PELVIS WITH IV CONTRAST, (DLP 3,177 mGy-cm):

REASON FOR EXAMINATION: Malignant neoplasm of the colon.

FINDINGS: Comparison is made to prior scan dated [REDACTED] +2571

CHEST: The lungs are clear. There is no evidence of metastatic disease. Normal heart size. There is no pneumonia, congestive heart failure or effusions. No mediastinal lymph node. Right-sided Port-A-Cath is not visualized.

ABDOMEN: The liver, spleen and pancreas are normal. There has been a cholecystectomy. There is no bile duct dilatation. Adrenal glands and kidneys are within normal limits except for a simple cyst 1 cm in size in the left kidney and a 3-mm calcification in the left kidney which probably represent vascular calcification rather than a stone. Visualized small and large bowel are grossly within normal limits with no evidence of any recurrent mass. No enlargement of mesenteric or retroperitoneal lymph nodes.

PELVIS: Within the pelvis, there has been a hysterectomy. There is an end to end anastomosis in the sigmoid colon.

IMPRESSION:

No CT evidence of metastatic disease. Multilevel degenerative changes.

[REDACTED]

[REDACTED]

[REDACTED]

[page 24 of 24]
This study was interpreted by:

This report has been reviewed and released by:

PACS Images

Show images for CT CHEST ABDOMEN PELVIS W IV CONTRAST

Patient Release Status:

This result is viewable by the patient in

In Basket Reviewed

Discharge Instructions

None

Additional Order Information

Open Additional Information

Order

CT CHEST ABDOMEN PELVIS W IV CONTRAST

Order Providers

Authorizing

Encounter

Billing

Order Information

Date

Department

Ordering/Authorizing

+2779

Start Date/Time

Start Date

Start Time

+2782

In Basket Reviewed

Order-Level Documents:

+2782 Scan on

+2782 Scan on

CONSENT ADMINISTRATION OF IV CONTRAST
GLUCOPHAGE OUTPATIENT

Original Order

Ordered On

Ordered By

Order #

Release Information

Released On

Released By

Associated Diagnoses

Malignant neoplasm of colon, unspecified site [153.9]

(MR

Source: NCI Genomic Data Commons file 869bab11-2b30-41a7-91e7-31ee9a3d1cdf (ER0117 ER-ABSE Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).